Gene-level copy-number profile of tumor specimen TCGA-96-7545-01A from TCGA case TCGA-96-7545, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.2 years (26,729 days).
Specimen TCGA-96-7545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3a8e8835-b7ac-421d-bad8-9a94c154a6e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-96-7545-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb71fe50-f1d9-4253-b910-6d229b761f04

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 34; copy number 2: 22,044; copy number 3: 13,667; copy number 4: 18,565; copy number 5: 3,177; copy number 6: 782; copy number 7: 282; copy number 8: 309; copy number 14: 909; copy number 22: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-96-7545-01A-21D-2041-01): tumor purity 0.4, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,510 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,749,342–246,507,312, 6 genes, copy number 7 (within-gene range 3–7): SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1.
- chr2:46,568,256–76,698,996, 556 genes, copy number 5–22 (within-gene range 4–22) (broad region; genes not listed).
- chr3:147,393,422–198,222,513, 909 genes, copy number 14 (within-gene range 2–14) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr6:167,607–33,339,495, 992 genes, copy number 5 (broad region; genes not listed).
- chr8:48,710,789–56,075,274, 96 genes, copy number 5–6 (broad region; genes not listed).
- chr8:56,917,084–75,034,558, 283 genes, copy number 5 (broad region; genes not listed).
- chr8:75,167,704–75,176,656, 1 gene, copy number 5: LINC02886.
- chr8:118,620,498–132,013,642, 200 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:69,909,184–70,436,584, 21 genes, copy number 6: AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 6: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr19:32,345,594–41,307,787, 439 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr22:15,290,718–24,008,258, 527 genes, copy number 5 (broad region; genes not listed).
- chr22:26,597,028–50,801,309, 766 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
